Surgical pathology report (de-identified scan), TCGA case TCGA-60-2715, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2715-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. LEFT UPPER LOBE WEDGE RESECTION
B. LEFT UPPER LOBECTOMY
C. LEVEL 10
D. LEVEL 5

CLINICAL HISTORY:

Hx total laryngectomy for squamous cell carcinoma

PRE-OPERATIVE DIAGNOSIS:

Squamous cell carcinoma of larynx

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Left upper lobe wedge resection: Non-small cell carcinoma (favor squamous cell carcinoma).

[REDACTED]

ESB: Left upper lobe lobectomy: Bronchial margins-negative for tumor.

[REDACTED]

GROSS DESCRIPTION:

A. LUNG, LEFT UPPER LOBE WEDGE RESECTION

Received fresh labeled with the patients name [REDACTED] left upper lobe wedge resection" is a wedge of mottled pink-black-tan lung tissue weighing 28.7 gm. It measures 8.0 x 5.0 x 3.0 cm with the stapled surgical margin inked blue. In the mid portion of the specimen, situated 0.5 cm from the stapled margin, is a area of puckering. This area is inked. Cut sections shows There is a partly anthracotic hemorrhagic firm mass measuring 1.5 x 1.0 x 1.0 The remainder of the lung parenchyma shows congestion.. Multiple sections are submitted in cassettes labelled as follows:

FSA1: frozen section of mass

A2-A4: remainder of mass including pleural and surgical margins

[page 2 of 3]
[REDACTED]

A5: section normal appearing parenchyma

B. LUNG, LEFT UPPER LOBECTOMY:

Received fresh and labeled with the patients name [REDACTED] "left upper lobe" is a lobectomy specimen weighing 114 gm and measuring 18.5 x 13 x 2.5 cm. The pleural surface is unremarkable. A shaved sectioned is taken of the bronchial margin. The bronchi are opened and they are smooth and tan in coloration. The serial cut sections show congestion with no other identifiable tumor focus. Sections are submitted as follows:

FSB1: frozen shaved section of bronchial margin

B2-B4: random sections of parenchyma

B5: possible lymph nodes

C. LEVEL 10

Received in formalin and labeled with the patients name [REDACTED] "c. level 10" is a lymph node measuring 2.0 x 0.9 x 0.5 cm. It is bisected and the cut surface has a variegated pink and black coloration. Submitted entirely in block C1.

D. LEVEL 5

Received in formalin and labeled with the patients name [REDACTED] "d. level 5" is a lymph node measuring 1.0 x 0.5 x 0.4 cm. Bisected, the cut surface has an anthracotic coloration. Submitted entirely in block D1.

[REDACTED]

DIAGNOSIS:

A. LUNG, LEFT UPPER LOBE, WEDGE RESECTION:

- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- SIZE OF TUMOR – 1.5 X 1.0 CM.
- CONGESTION AND FOCAL EMPHYSEMATOUS CHANGE.

See note

B. LUNG, LEFT UPPER LOBECTOMY:

- CONGESTION, FOCAL EMPHYSEMATOUS CHANGE.
- FIVE PERIBRONCHIAL LYMPH NODES – NEGATIVE FOR TUMOR (0/5).
- BRONCHIAL MARGINS OF RESECTION - NEGATIVE FOR TUMOR.
- NEGATIVE FOR RESIDUAL CARCINOMA.

C. LEVEL 10 LYMPH NODE – THREE LYMPH NODES – NEGATIVE FOR TUMOR (0/3).

D. LEVEL 5 LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

Note: Patient had previous history of diagnosis of f squamous cell carcinoma of glottic larynx on [REDACTED]. Immunostain for TTF1 (A3) is negative. It is difficult to say for sure if current lung lesion is a primary or a metastatic tumor. See also pathology report [REDACTED].

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

[REDACTED]

[page 3 of 3]
Material: Block A3

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
TTF-1	Negative	

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the [REDACTED]. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology [REDACTED] determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 7a1390ed-ccf4-4aa1-988b-3bf3e138d362 (TCGA-60-2715.3378CD9A-00EA-42F9-9884-A72A54F1DD32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).